Somatic mutation profile of tumor specimen C3L-05335-54 (aliquot CPT0303780002) from CPTAC case C3L-05335, project CPTAC-3 (Hematopoietic and reticuloendothelial systems — Myeloid Leukemias). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 42.6 years (15,545 days).
Specimen C3L-05335-54: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 283a520b-24c0-4735-a2fa-c0f07b9f6330.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05335-50 (Buccal Cell Normal), aliquot CPT0303900001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/40d5d382-dd78-4376-a14c-33519e654d7b

The open-access MAF lists 8 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 2, Intron 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 200/868 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- CYP4B1 | c.110A>T p.Q37L | Missense Mutation (SNP) | VAF 192/465 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC6A1 | c.1582G>A p.V528I | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- C19orf47 | c.273C>A p.G91= | Silent (SNP) | VAF 214/507 reads (42%) | catalogued as COSV63508375; called by muse, mutect2, varscan2
- COBLL1 | c.2484C>T p.T828= (on ENST00000392717; = p.T790= on NM_014900.5) | Silent (SNP) | VAF 14/268 reads (5%) | called by muse, mutect2
- BAIAP2 | c.1535+510C>T | Intron (SNP) | VAF 86/317 reads (27%) | catalogued as rs756593787; called by muse, mutect2, varscan2
- FMO9P | n.439G>A | RNA (SNP) | VAF 80/206 reads (39%) | called by muse, varscan2
- SLC16A10 | c.942+802C>T | Intron (SNP) | VAF 73/168 reads (43%) | catalogued as rs148402763, COSV64354064; called by muse, mutect2, varscan2
